Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7089, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7089-01A (Primary Tumor).

[page 1 of 2]
** Case imported from legacy computer system. The format of this report does not match the original case. **
** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. **

DIAGNOSIS

(A) TOTAL LARYNGOPHARYNGECTOMY, LEFT THYROID LOBECTOMY, AND BILATERAL MODIFIED NECK DISSECTION:
INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA OF PHARYNX, LEFT POSTERIOR WALL, MAXIMUM DIMENSION 4.5 CM, WITH LYMPHOVASCULAR INVASION.
TWO PERITUMORAL DEPOSITS OF SQUAMOUS CELL CARCINOMA, POSSIBLY REPRESENTING TWO COMPLETELY REPLACED LYMPH NODES.
METASTATIC SQUAMOUS CELL CARCINOMA IN 1 OF 10 RIGHT CERVICAL LYMPH NODES (1/6 LEVEL I, 0/3 LEVEL II, 0/1 LEVEL III).
METASTATIC SQUAMOUS CELL CARCINOMA IN 5 OF 10 (5/10) LEFT CERVICAL LYMPH NODES (2/3 LEVEL I, 1/3 LEVEL II, 2/4 LEVEL III).
Margins free of tumor.
Thyroid gland, no tumor present.
Vocal cords, bilateral, no tumor present.

Entire report and diagnosis completed by: [REDACTED]

GROSS DESCRIPTION

(A) BILATERAL MODIFIED NECK DISSECTION, TOTAL LARYNGOPHARYNGECTOMY AND LEFT THYROID LOBECTOMY - The product of bilateral neck dissection and laryngopharyngectomy with overall measurements of 9.5 x 6.5 x 5.0 cm. On the superior pharyngeal wall mainly on the left and posterior aspect, is a multinodular ulcerated and indurated mass measuring 4.5 x 4.0 x 1.0 cm. The larynx mucosa appears unremarkable. The tumor appears surrounded by normal appearing mucosa and does not involve any of the margins of resection grossly. Two separate 1.0 x 1.0 cm nodules attached to the superior aspect of the pharyngeal-laryngeal wall are noted and are submitted separately.

Representative sections are submitted as follows:

SECTION CODE: A1-A9, margins for frozen section; A1, inferior pharyngeal margin; A2, A3, 9 to 12 o'clock, posterior margin; A4, A5, posterior margin; A6, A7, base of tongue; A8, A9, base of tumor from 6 to 9 o'clock; A10, section of thyroid; A11, right vocal cord; A12, left vocal cord; A13-A32, sequential sections from posterior left to anterior of the lesion; A33, representative section of the two lymph nodes; A34, one lymph node, right neck level I; A35, one lymph node, right neck level I; A36, five lymph nodes, right neck level I; A37, two lymph nodes, right neck, level II; A38, two lymph nodes, right neck, level II; A39, one lymph node, right neck level III; A40, one lymph node, left neck level I, grossly positive; A41, two lymph nodes, left neck, level I; A42, one lymph node, left neck level II; A43, one lymph node, left neck level II; A44, one lymph node, left neck level II; A45, one lymph node, left neck level III; A46, three lymph nodes, left neck, level III. [REDACTED]

[page 2 of 2]
*FS/DX: NO TUMOR PRESENT, PROXIMAL MUCOSAL MARGINS, FOCAL ATYPIA, MARGINS
FREE OF TUMOR.

SNOMED CODES

M-80703 M-80706 T-55000 T-C4200

Source: NCI Genomic Data Commons file 0f83f4f8-0885-4018-8abb-d6fd9482ce5a (TCGA-CV-7089.5F81EAEE-A45D-4CE4-8A4B-7AFFEF02E0E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).